Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3538, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3538-01A (Primary Tumor).

*** Diagnosis/Diagnoses: ***

1.: Excision specimen from peritoneum with angiectasia and subserosal fibrosis.

2.: Colonic resection specimen (evidently sigmoid) with an ulcerated carcinoma of the colon of the histological type of a moderately differentiated colorectal adenocarcinoma, measuring 2 cm in its largest diameter and extending to a maximum of 8 cm from the resection margin. Invasive tumor spread to the level of the muscularis propria.

Oral and aboral resection margin tumor-free.

Twenty-six mesocolic lymph nodes tumor-free and with uncharacteristically reactive changes.

Tumor stage therefore pT2 pN0 (0/26) L0 V0; G2 R0.

Source: NCI Genomic Data Commons file a2373028-01fb-417e-81b5-bdb8f126654c (TCGA-AA-3538.32912174-66B8-4144-9EF0-26B04C05E568.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).